Surgical pathology report (de-identified scan), TCGA case TCGA-98-A53I, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - Alabama, specimen TCGA-98-A53I-01A (Primary Tumor).

[page 1 of 4]
Patient Name	MR#	Observation Date	Last Edited Date
--------------	-----	------------------	------------------

SURGICAL PATHOLOGY CASE:

Diagnosis: A. Soft tissue mass, chest wall, right, excision: - Mature adipose tissue, consistent with lipoma, size 14x10 cm, see comment.

- B. Lymph node, level VII, lymph node, excision: - Negative for malignancy.
- C. Lymph node, level VII, excision: - Negative for malignancy.
- D. Lymph node, level IX, excision: - Negative for malignancy.
- E. Lymph node, level VIII, excision: - Negative for malignancy.
- F. Lymph node, level VIII, excision: - Fibroadipose tissue. - Negative for malignancy. - No lymph node identified.
- G. Lymph node, level VIII, excision: - Negative for malignancy.
- H. Lymph node, level IX, excision: - Fibroadipose tissue. - Negative for malignancy. - No lymph node identified.
- I. Lymph node, level VII, excision: - Negative for malignancy.
- J. Lymph node, level VII, excision: - Negative for malignancy.
- K. Lymph node, level VII, excision: - Negative for malignancy.
- L. Lymph node, level VII, excision: - Negative for malignancy.
- M. Lymph node, level VII, excision: - Negative for malignancy.
- N. Lymph node, level VII, excision: - Negative for malignancy.
- O. Lymph node, level X, excision: - Negative for malignancy.
- P. Lymph node, level X, excision: - Negative for malignancy.
- Q. Lymph node, level XI, excision: - Negative for malignancy.
- R. Lymph node, level XI, excision: - Negative for malignancy.

ICB-0-3
carcinoma, squamous cell, NOS 8070/3
Site: lung, (R) upper lobe C34.1
fw
11/25/12

S. Lung, right upper lobe, lobectomy: - Moderately differentiated (size ~ 3.3 cm) squamous cell carcinoma, endobronchial, fragmented. See comment. - Tumor is near the staple line, final margin is free. - Tumor does not involve pleura. - Metastatic carcinoma seen in one of five peribronchial lymph nodes (1/5). - Pathologic stage: pT2a, N1, Mx - There are several hyalinized granulomas. - Non neoplastic parenchyma shows mild centriacinar emphysema.

- T. Bronchial margin, excision: Negative for malignancy.
- U. Lymph node, level IV, excision: - Negative for malignancy.
- V. Lymph node, level IV, excision: - Negative for malignancy. - Hyalinized calcified granuloma.
- W. Lymph node, level IV, excision: - Negative for malignancy. - Hyalinized calcified lymph node.
- X. Lymph node, level IV, excision: - Negative for malignancy. - Hyalinized calcified lymph node.
- Y. Lymph node, level IV, excision: - Negative for malignancy.
- Z. Lymph node, level II, excision: - Negative for malignancy. - Hyalinized calcified granuloma.
- AA. Lymph node, level II, excision: - Negative for malignancy. - Hyalinized calcified granuloma.
- BB. Lymph node, level II, excision: - Negative for malignancy. - Hyalinized calcified granuloma.

CC. Lymph node, left main stem, excision: - Blood and adipose tissue. - Negative for malignancy. - No lymph node identified.

Pathologist Comments

Due to the fragmented nature of the specimen the tumor size is estimated to be 3.3 cm, based on radiologic study.
Due to the large size of the chest wall lipoma, local recurrence may occur.

Clinical Information: This is a -year-old man with lung cancer.

Frozen Section Diagnosis

- S1: Lung, right upper lobe, resection: - Squamous cell carcinoma.
- U1: Bronchial margin, excision: - Negative for malignancy

Gross Description

[page 2 of 4]
The specimens are received in twenty-nine containers, each in formalin and each marked with the patient's name and medical record number. Additionally, the first container is labeled "chest wall tumor, right side, final." Within this container, we have a solitary mass which is yellow in color with various attachments of fascial tissue and skeletal muscle. Overall, this tissue measures 14.0 x 10.0 x 6.5 cm. It is very firm with no cystic features on the outside. It appears to be invested in a thin fascial layer. The outside will be inked green prior to serial sectioning. The composition appears to be fatty in nature. The specimen is serially sectioned revealing a homogeneous fat-like consistency which appears to be entirely inscribed by the green ink. No necrosis is noted. Representative sections are submitted into cassettes A1-A14.

The second container is additionally labeled "level VII lymph node." Within this container, we have a 1.0 x 1.5 cm tan-black fragmented tissue. It is submitted in its entirety into B1.

The third container is additionally labeled "level VII lymph node." Within this container, we have a 1.5 x 0.7 fragment of tan- black tissue. It is submitted in its entirety into cassette C1.

The fourth container is additionally labeled "level IX lymph node." Within this container, we have a 1.0 x 0.7 cm piece of tan fragment tissue that is submitted in its entirety into cassette D1.

The fifth container is additionally labeled "level VIII lymph node." Within this container, we have a single piece of tissue which is tan-black in color. It measures 0.3 x 0.5 cm. It is submitted in its entirety into cassette E1.

The sixth container is additionally labeled "level VIII lymph node." Within this container, we have a single piece of tan-brown tissue which measure 0.5 x 0.3 cm. It is submitted in its entirety into cassette F1.

The seventh container is additionally labeled "level VIII lymph node." Within this container, we have a single fragment of tan- black tissue which measures 0.5 x 0.6 cm. It is submitted in its entirety into cassette G1.

The eighth container is additionally labeled "level IX lymph node." Within this container, we have a single fragment of tan- black tissue measuring 0.5 x 0.4 cm. It is submitted in its entirety into cassette H1.

The ninth container is additionally labeled "level VII lymph node." Within this container, we have a 1.2 x 0.9 cm piece of tan- black tissue. It is submitted in its entirety into cassette I1.

The tenth container is additionally labeled "level VII lymph node." Within this container, we have three fragments of tan-black tissue which measure in aggregate 1.0 x 1.2 cm. These are submitted in their entirety into cassette J1.

The eleventh container is additionally labeled "level VII lymph node." Within this container, we have a single fragment of tan- black tissue which measures 1.5 x 0.4 cm. It is submitted in its entirety cassette K1.

The twelfth container is additionally labeled "level VII lymph node." Within this container, we have two fragments of tan-black tissue which measure in aggregate 1.0 x 1.0 cm. These are submitted in their entirety into cassette L1.

The thirteenth container is additionally labeled "level VII lymph node." Within this container, we have a single fragment of tissue measuring 1.2 x 0.5 cm. It is tan-black in color and submitted in its entirety into cassette M1.

The fourteenth container is additionally labeled "level VII lymph node." Within this container, we have a single fragment of tan-brown material which measures 1.1 x 0.5 cm. It is submitted in its entirety in N1.

The fifteenth container is additionally labeled "level X lymph node." Within this container, we have a single fragment of tan- black tissue which measures 1.1 x 0.5 cm. It is submitted in its entirety into cassette O1.

The sixteenth container is additionally labeled "level X lymph node." Within this container, there is a piece of black-tan tissue measuring 0.5 x 0.5 cm. It is submitted in its entirety into cassette P1.

The seventeenth container is additionally labeled "level XI lymph node." Within this container, we have a piece of tan-black tissue which measures 0.4 x 0.4 cm. It is submitted in its entirety into cassette Q1.

The eighteenth container is additionally labeled "level XI lymph node." Within this container, we have a single fragment of tan-black tissue which measures 0.4 x 0.5 cm. It is submitted in its entirety in R1.

The nineteenth container is additionally labeled "right upper lobe." Within this container, we have an orange cassette labeled with the patient's name and date of birth and S1. Within this container, these are remnant frozen sections, and measure 2.0 x 2.0 cm in aggregate. They are submitted in their entirety into cassette S1. Within this container, we have

[page 3 of 4]
a lobe of lung. The lobe of lung measures 18.5 x 14.0 x 4.8 cm. The hilar surface has what appears to be a nodule attached to the side of the hilar vessels. Otherwise, the hilar surface is smooth and shiny. There is some mucous which is coming out of the bronchus. The anti hilar surface of the lung is shiny pink with no obvious nodules. Additionally, there is a staple line which measures 10.0 cm in length and comes to within 0.2 cm of the previously opened associated mass. There is a second staple line which measures 5.0 cm which is on the lower aspect of the bronchial margins. Again, beside the one lesion at the bronchus, there is no other additional lesions noted on the pleural surface. Representative sections are taken of the lesion which is adjacent to the bronchial margins. This tissue is white with coarse black heterogenous parts. They appear to be attached to a cartilaginous structure. These are submitted into S2 and S3. Additional sections are taken at the hilum of a solid lesion which is more inferior to the aforementioned lesion. Of note, the lesion is hard to evaluate in terms of size, due to the fact that it has been previously sectioned. A piece of potential lesion, which is adjacent to the inferior staple line, is placed into cassette S5. An additional portion of the apparent tumor is submitted with respect to the other staple line. This is submitted into cassette S6. Serial sectioning of the lung does not reveal any additional masses, nodules, or cysts. There is a firm pink parenchyma with minimal anthracosis. There is one hard nodule which is identified and extracted. This appears to be an old calcified lymph node. A representative section is submitted into S7. Representative samples of the remainder of the lung are submitted into cassettes S8 and S10.

The twentieth container is additionally labeled "bronchial margin." Within this container, we have a single cassette marked with the patient's name, date birth, and U1. Within this container, we have a fragment of white tissue which measures 0.6 x 0.5 cm. It is submitted in its entirety into cassette T1.

The twenty first container is additionally labeled "level IV lymph node." Within this container, we have a single fragment of tan-black tissue which in aggregate measures 1.0 x 0.9 cm. It is submitted in its entirety into cassette U1.

The twenty second container is additionally labeled "level IV lymph node." Within this container, we have a single fragment of tan-brown material which measures 1.1 x 0.6 cm. It is submitted in its entirety into cassette V1.

The twenty third container is additionally labeled "level IV lymph node." Within this container, we have two fragments of tan- black tissue which measure 1.1 x 0.6 cm in aggregate. The tissues are submitted into cassette W1.

The twenty fourth container is additionally labeled "level IV lymph node." Within this container, we have multiple fragments of tan-black material which in aggregate measures 1.5 x 1.0 cm. This is submitted in its entirety into cassette X1.

The twenty fifth container is additionally labeled "level IV lymph node." Within this container, we have a single fragmented tan-brown tissue measuring 0.1 x 0.8 cm. It is submitted in its entirety into Y1.

The twenty sixth container is additionally labeled "level II lymph node." Within this container, we have a piece of white tissue which in aggregate 1.0 x 0.8 cm. It is submitted in its entirety into Z1.

The twenty seventh container is additionally labeled "level II lymph node." Within this container, we have a single fragment of white tissue measuring 0.4 x 0.3 cm. It is submitted in its entirety into cassette AA1.

The twenty eighth container is additionally labeled "level II lymph node." Within this container, we have a single fragment of white tissue which measures 0.3 x 0.2 cm. It is submitted in its entirety into cassette BB1.

The twenty ninth container is additionally labeled "left main stem lymph node." Within this container, we have a single fragment of tan-black material measuring 1.0 x 0.6 cm. It is submitted in its entirety into cassette CC1.

Block Summary

A1-A14 Chest wall tumor, representative sections.

B1- Level VII lymph node.

C1- Level VII lymph node.

D1- Level IX lymph node.

E1- Level VIII lymph node.

F1- Level VIII lymph node.

G1- Level VIII lymph node.

H1- Level IX lymph node.

I1- Level VII lymph node.

J1- Level VII lymph node.

K1- Level VII lymph node.

L1- Level VII lymph node.

[page 4 of 4]
M1- Level VII lymph node.
N1- Level VII lymph node.
O1- Level X lymph node.
P1- Level X lymph node.
Q1- Level XI lymph node.
R1- Level XI lymph node.
S1- Remnant frozen section, right upper lobe.
S2-S4 Tumor adjacent to cartilaginous structure.
S5 Adjacent to staple line.
S6- A section of potential tumor adjacent to other staple line.
S7- Calcified lymph node.
S8-S10 Uninvolved lung parenchyma.
T1- Bronchial margin.
U1- Level IV lymph node.
V1- Level IV lymph node.
W1- Level IV lymph node.
X1- Level IV lymph node.
Y1- Level IV lymph node.
Z1- Level II lymph node.
AA1- Level II lymph node.
BB1- Level II lymph node.
CC1- Left main stem lymph node.

Microscopic Description: A microscopic examination has been performed.

SP Synoptic Report S: Thorax Lung

SPECIMEN: Lobe(s) of lung: right upper lobe

PROCEDURE: Lobectomy

SPECIMEN INTEGRITY: Disrupted

SPECIMEN LATERALITY: Right

TUMOR SITE: Upper lobe

TUMOR SIZE: Cannot be determined

TUMOR FOCALITY: Unifocal

HISTOLOGIC TYPE: Squamous cell carcinoma

HISTOLOGIC GRADE: G2: Moderately differentiated

VISCERAL PLEURA INVASION: Not identified

TUMOR EXTENSION: Not applicable

BRONCHIAL MARGIN: Uninvolved by invasive carcinoma

VASCULAR MARGIN: Uninvolved by invasive carcinoma

PARENCHYMAL MARGIN: Uninvolved by invasive carcinoma

PARIETAL PLEURAL MARGIN: Not applicable

CHEST WALL MARGIN: Not applicable

TREATMENT EFFECT: Not applicable

LYMPH-VASCULAR INVASION: Not identified

PRIMARY TUMOR (pT): pT2a: Tumor > 3 cm, and < 5 cm in greatest dimension surrounded by lung or visceral pleura, without bronchoscopic evidence of invasion in the main bronchus; or Tumor < 5 cm in greatest dimension with any of the following: involves main bronchus, 2 cm or more distal to the carina; invades the visceral pleura; associated with atelectasis or obstructive pneumonitis that extends to the hilar region

REGIONAL LYMPH NODES (pN): pN1: Metastasis in ipsilateral peribronchial and/or ipsilateral hilar lymph nodes, and intrapulmonary nodes, including involvement by direct extension

DISTANT METASTASIS (pM): Not applicable

Diagnostic Discrepancy		✓

11/25/12

Source: NCI Genomic Data Commons file 3026b3de-4198-4d27-a42c-5bee3730ad3f (TCGA-98-A53I.D5167627-2D4D-4210-BAFC-CD73555488D9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).